MMRF case MMRF_2428 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6b9d857e-e76b-4901-8959-506801628eaf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.2 years (19,783 days); ISS stage: I; Days to last known disease status: 715 days (2.0 years); Days to last follow up: 715 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Carfilzomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 191 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 197 days; Days to treatment end: 224 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 261 days; Days to treatment end: 261 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 263 days; Days to treatment end: 263 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 351 days; Days to treatment end: 357 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 351 days; Days to treatment end: 385 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 351 days; Days to treatment end: 378 days (1.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 365 days (1.0 years); Days to treatment end: 385 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 379 days (1.0 years); Days to treatment end: 385 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 407 days (1.1 years); Days to treatment end: 434 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 435 days (1.2 years); Days to treatment end: 715 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 715 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 2.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 339 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 7.7 g/L; Immunoglobulin A 33.4 g/L; Immunoglobulin M 1.33 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 83 µmol/L; Calcium 2.49 mmol/L; Albumin 40 g/L; Total Protein 9.8 g/dL; Glucose 4.6 mmol/L; C-Reactive Protein 0.9 mg/dL.
- Day 92 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.29 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.9 mmol/L.
- Day 176 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 1.1 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70 µmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.7 mmol/L.
- Day 246 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 4.6 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.58 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 74 µmol/L; Calcium 2.17 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 5 mmol/L.
- Day 351 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 73 µmol/L; Calcium 2.27 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.4 mmol/L.
- Day 434 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 4.9 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.2 mmol/L.
- Day 547 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 4.7 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 4.35 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 77 µmol/L; Calcium 2.34 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 631 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 4.3 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 5.03 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 72 µmol/L; Calcium 2.19 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.4 mmol/L.
- Day 715 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 4.4 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 4.57 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 74 µmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.3 mmol/L.

Other clinical attributes
- Day -7: Weight: 92 kg; Height: 186 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2428_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2428_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
